Somatic mutation profile of tumor specimen TCGA-UD-AAC4-01A (aliquot TCGA-UD-AAC4-01A-11D-A39R-32) from TCGA case TCGA-UD-AAC4, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 65.6 years (23,949 days).
Specimen TCGA-UD-AAC4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 425d4791-ff3d-4b94-85e0-6f6a74b140d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UD-AAC4-10A (Blood Derived Normal), aliquot TCGA-UD-AAC4-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7ed8708-1d77-42e7-a810-4be4095c8104

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Splice Site 2, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.660-2A>G p.X220_splice | Splice Site (SNP) | VAF 25/87 reads (29%) | catalogued as rs1559589809; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.4955G>A p.R1652Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763532229, COSV55208487; called by muse, mutect2, varscan2
- CAMSAP3 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs746780174; called by muse, mutect2, varscan2
- CNTN5 | c.3016G>A p.V1006I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200028794, CM1513337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1H1 | c.2671C>T p.H891Y | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1442965290; called by muse, mutect2, varscan2
- HAP1 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV57880492; called by muse, mutect2, varscan2
- NCAN | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs776226614; called by muse, mutect2, varscan2
- NRP1 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766101815, COSV55172442; called by muse, mutect2, varscan2
- PPM1H | c.778_779del p.R260Efs*4 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1348961598; called by pindel, varscan2
- RPS6KB2 | c.1155+1G>A p.X385_splice | Splice Site (SNP) | VAF 103/340 reads (30%) | catalogued as COSV57047506; called by muse, mutect2, varscan2
- SFXN4 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100340904; called by muse, mutect2, varscan2
- SHROOM1 | c.2036G>A p.W679* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV60581678; called by muse, mutect2, varscan2
- SLC15A4 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57161758; called by muse, mutect2, varscan2
- SLC22A11 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as rs762166460, COSV57253544; called by muse, mutect2, varscan2
- TRPA1 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV51558521; called by muse, mutect2, varscan2
- CNTRL | c.6118G>A p.E2040K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRYBG1 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FAT4 | c.7444C>G p.L2482V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FRY | c.5179G>C p.A1727P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEDD1 | c.700T>A p.Y234N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NPTX1 | c.405A>C p.Q135H | Missense Mutation (SNP) | VAF 165/549 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PHTF2 | c.671C>A p.T224K (on ENST00000248550 / NM_001366089.1; = p.T186K on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- REV3L | c.5700_5701insTT p.E1901Lfs*30 | Frame Shift Ins (INS) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- SLC25A31 | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- UPF1 | c.1260C>G p.F420L (on ENST00000599848 / NM_001297549.2; = p.F409L on NM_002911.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CRIM1 | c.54C>G p.V18= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- FAM47A | c.1197C>T p.L399= | Silent (SNP) | VAF 56/99 reads (57%) | called by muse, mutect2, varscan2
- HELZ2 | c.1095C>T p.T365= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV64409394; called by muse, mutect2, varscan2
- MAP6D1 | c.96C>T p.G32= | Silent (SNP) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- MFSD2A | c.51C>T p.P17= | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as rs1220764780; called by muse, mutect2, varscan2
- RTTN | c.1821C>T p.A607= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs1200271202; called by muse, mutect2, varscan2
- SYNPO2L | c.1836G>A p.Q612= (on ENST00000394810 / NM_001114133.3; = p.Q388= on NM_024875.5) | Silent (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- OR2U1P | n.311C>T | RNA (SNP) | VAF 21/100 reads (21%) | catalogued as rs369399120; called by muse, mutect2, varscan2
